FM case AD4861 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Germ Cell Neoplasms; Primary site: Heart, mediastinum, and pleura.
https://portal.gdc.cancer.gov/cases/51264842-e5a9-4595-b1a2-bb8709839cc5

Male, 51.2 years: Germ cell tumor, NOS (ICD-O-3 9064/3) of the mediastinum; primary biopsied or resected from the mediastinum. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
